Somatic mutation profile of tumor specimen TARGET-10-PATMTV-09A (aliquot TARGET-10-PATMTV-09A-01D) from TARGET case TARGET-10-PATMTV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,045 days).
Specimen TARGET-10-PATMTV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0ec039e-29ab-44cc-bb1e-b6209a52657b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATMTV-10A (Blood Derived Normal), aliquot TARGET-10-PATMTV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9aa38e3b-c3b7-4644-b6f6-6878e3644afd

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, 5'UTR 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.2173C>A p.Q725K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51942825; called by muse, mutect2, varscan2
- EDNRA | c.409A>G p.N137D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as COSV60098791; called by muse, mutect2, varscan2
- EFTUD2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53656001; called by muse, mutect2, varscan2
- FBXO40 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs141957650, COSV57525207; called by muse, mutect2, varscan2
- FRAS1 | c.9448G>A p.V3150M | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53625751; called by muse, mutect2, varscan2
- GAP43 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV59342793; called by muse, mutect2
- KRT39 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.302); catalogued as rs373584744, COSV62917538; called by muse, mutect2, varscan2
- PRF1 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV64615417; called by muse, mutect2, varscan2
- VXN | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as rs758981792, COSV59686070; called by muse, mutect2, varscan2
- MICAL2 | c.3939G>A p.S1313= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs182474608; called by muse, mutect2, varscan2
- NTN4 | c.585+128A>T | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.1641+151G>A | Intron (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- RNF212 | c.362+13A>C | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, varscan2
- RPL7P3 | chr20:62570579 A>G | 5'Flank (SNP) | VAF 42/87 reads (48%) | catalogued as rs1555904362; called by muse, mutect2, varscan2
- VANGL2 | c.-37G>A | 5'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as rs1212214660; called by muse, mutect2, varscan2
